Surgical pathology report (de-identified scan), TCGA case TCGA-XF-A9SV, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Southern California, specimen TCGA-XF-A9SV-01A (Primary Tumor).

[page 1 of 7]
SURGICAL PATHOLOGY REPORT

* Final Report *

ICD-O-3
Carcinoma, urothelial papillary
Site Bladder NOS C67.9
8/30/13
JWS/26/14

Document Type:
*Date - Date of Service:
Document Status:
Document Title:
Author:
Authenticated By:
Encounter info:
Contributor system:

* Final Report *

MICROSCOPIC EXAMINATION:

A-D: See final microscopic-diagnoses.

E: Sections of the urinary bladder show invasive, moderately to poorly differentiated papillary urothelial carcinoma, characterized by single strands and small nests of enlarged malignant cells with correspondingly enlarged nucleoli and scanty cytoplasm. The tumor extends through the full thickness of the bladder wall and involves seminal vesicles, vasa deferentia, and rectum. The tumor cells involve serosa, muscularis propria, and is attached to the underlying surface of the rectal mucosa. The distal resection margin of the rectum is involved by tumor. The proximal resection margin is free of tumor. There is extensive perineural and lymphovascular space invasion. Bilateral ureteral mucosa show mild to severe atypia. Representative sections of prostate are unremarkable.

F-Q: See final microscopic-diagnoses.

INTRAOPERATIVE FROZEN CONSULTATION:

AFS: Periaorta:

- metastatic carcinoma

BFS: Right perirenal lymph node:

- metastatic carcinoma

CFS: Right ureter:

- mild to moderate atypia of ureter
- metastatic urothelial carcinoma

DFS: Left ureter:

- severe dysplasia of ureter

Printed by:
Printed on:

Page 1 of 7
(Continued)

[page 2 of 7]
SURGICAL PATHOLOGY REPORT

* Final Report *

GROSS EXAMINATION:

A: The specimen is received fresh from the O.R. and labelled "Retroperitoneum" (Periaortic). It consists of a piece of tan-yellow soft tissue measuring 0.8 x 0.8 x 0.4 cm. The specimen is entirely submitted for frozen section in cassette AFS.

B: The specimen is received fresh from the O.R. and labelled "Right perirenal FS". It consists of a piece of tan soft tissue measuring 5 x 0.8 x 0.4 cm. Half of the specimen is submitted for frozen section and the remaining tissue is submitted for permanent section.

C: The specimen is received fresh from the O.R. and labelled "Rt ureter". It consists of ureter measuring 0.5 cm in length and 0.4 cm in diameter and surrounding soft tissue measuring 0.7 x 0.5 x 0.4 cm. The specimen is submitted for frozen section in cassette CFS

D: The specimen is received fresh from the O.R. and labelled "Lt ureter". It consists of ureter measuring 0.4 cm in length and 0.4 cm in diameter and surrounding soft tissue measuring 0.5 x 0.3 x 0.3 cm. The specimen is entirely submitted for frozen section in cassette DFS.

E: The specimen is received fresh from the O.R. and labelled "Bladder, prostate & rectum". It consists of prostate, urinary bladder, bilateral ureters, rectum and peritoneum. Overall, the specimen measures 13 x 18 x 5 cm. The peritoneum measures 15 x 5 x 0.1 cm. The bladder measures 8 x 5 x 2 cm. The rectum measures 20 cm in length and 7 to 10 cm in circumference. The prostate measures 6 x 5 x 5 cm. The prostate is opened anteriorly through the prostatic urethra and then the urinary bladder is opened anteriorly. There are multiple polypoid tumors in the urinary bladder mucosa measuring from 0.5 cm to 1.5 cm in greatest dimension. A polypoid tumor is adjacent to the left ureterovesical junction. The right ureterovesical junction is 1.5 cm from the closest polypoid tumor. The left ureter measures 5 cm in length and 0.6 cm in circumference. The right ureter measures 5 cm in length and 0.6 cm in circumference. There is a constricted area in the right ureter, which measures 0.3 cm in circumference and is approximately 1 cm from the right ureterovesical junction. This constriction is due to the deeply infiltrating tumor in the urinary wall around the ureter. The tumor also involves bilateral seminal vesicles and vasa deferentia. The tumor is close to but does not involve the colonic mucosa. The right resection margins appears grossly involved by tumor.

The prostate is cross sectioned perpendicular to the prostatic urethra and is unremarkable. The proximal and distal resection margins of the rectum are both grossly free of tumor. The peritoneum is unremarkable. Representative sections are submitted in a total of 15 cassettes.

F: The specimen is received in formalin and labelled "Right common iliac LN". It

Printed by:
Printed on:

Page 2 of 7
(Continued)

[page 3 of 7]
SURGICAL PATHOLOGY REPORT

* Final Report *

consists of a two pieces of tan soft tissue measuring 3 x 1.5 x 0.4 cm in aggregate. The specimen is entirely submitted in two cassettes.

G: The specimen is received in formalin and labelled "Para caval LN". It consists of two pieces of tan soft tissue measuring 2.2 x 0.8 x 0.4 cm in aggregate. The specimen is entirely submitted in one cassette.

H: The specimen is received in formalin and labelled "Left common iliac LN". It consists of two pieces of tan soft tissue measuring 2.5 x 1 x 0.4 cm in aggregate. The specimen is entirely submitted in one cassette.

I: The specimen is received in formalin and labelled "Right LN of Cloquet". It consists of a piece of soft tan tissue measuring 0.8 x 0.6 x 0.4 cm. The specimen is entirely submitted in one cassette.

J: The specimen is received in formalin and labelled "Rt external iliac LN". It consists of multiple tan soft tissue fragments measuring 4 x 1.5 x 0.2 cm in aggregate. The specimen is entirely submitted in three cassettes.

K: The specimen is received in formalin and labelled "Right hypogastric/obturator LN". It consists of multiple tan soft tissue fragments measuring 3 x 2 x 0.4 cm in aggregate. The specimen is entirely submitted in three cassettes.

L: The specimen is received in formalin and labelled "Left external iliac LN". It consists of multiple tan-yellow, soft, fibroadipose tissue fragments measuring 3.5 x 1.5 x 0.4 cm in aggregate. The specimen is entirely submitted in three cassettes.

M: The specimen is received in formalin and labelled "Left LN of Cloquet". It consists of a piece of tan soft tissue measuring 0.8 x 0.6 x 0.2 cm. Entirely submitted in one cassette.

N: The specimen is received in formalin and labelled "Left obturator/hypogastric lymph node". It consists of multiple tan-yellow fibroadipose tissue fragments measuring 3 x 2 x 0.4 cm in aggregate. The specimen is entirely submitted in three cassettes.

O: The specimen is received in formalin and labelled "Para aortic LN". It consists of two pieces of tan soft adipose tissue measuring 1.2 x 0.8 x 0.6 cm in aggregate. The specimen is entirely submitted in one cassette.

P: The specimen is received in formalin and labelled "Proximal left ureter". It consists a segment of ureter measuring 0.8 cm in length and 0.3 cm in diameter. The specimen is entirely submitted in one cassette.

Printed by:
Printed on:

Page 3 of 7
(Continued)

[page 4 of 7]
SURGICAL PATHOLOGY REPORT

* Final Report *

Q: The specimen is received in formalin and labelled "Right proximal ureter". It consists of a segment of ureter measuring 0.4 cm in length and 0.5 cm in diameter. The specimen is entirely submitted in one cassette.

SECTIONS:

AFS: frozen section, retroperitoneum - all embedded
BFS: frozen section, right perirenal
BRT: remaining tissue
CFS: frozen section, right ureter - all embedded
DFS: frozen section, left ureter - all embedded
E1: proximal resection margin of rectum
E2: distal resection margin of rectum
E3: rectal mucosa
E4: mucosa with adjacent tumor
E5: left ureterovesical junction
E6: right ureter in constricted area and ureterovesical junction
E7,8: urinary bladder mucosa, polypoid nodule
E9: vasa deferentia
E10: seminal vesicles
E11: right perivesical radial margin
E12: left perivesical radial margin
E13,14: prostate
E15: peritoneum
F1,2: right common iliac lymph node - all embedded
G: paracaval lymph node - all embedded
H: left common iliac lymph node - all embedded
I: right lymph node of Cloquet - all embedded
J1-3: right external iliac lymph node - all embedded
K1-3: right hypogastric/obturator lymph node - all embedded
L1-3: left external iliac lymph node - all embedded
M: left lymph node of Cloquet - all embedded
N1-3: left obturator/hypogastric lymph node - all embedded
O: para-aortic lymph node - all embedded
P: proximal left ureter - all embedded
Q: right proximal ureter - all embedded

Signature Line

CLINICAL INFORMATION:

Pre-Op Dx: Prostate cancer
Post-Op Dx: Same

Printed by:
Printed on:

Page 4 of 7
(Continued)

[page 5 of 7]
SURGICAL PATHOLOGY REPORT

* Final Report *

SPECIMEN SOURCE:

A: "Retroperitoneum" (Periaortic)
B: "Right perirenal FS"
C: "Rt ureter"
D: "Lt ureter"
E: "Bladder, prostate & rectum"
F: "Right common iliac LN"
G: "Para caval LN"
H: "Left common iliac LN"
I: "Right LN of Cloquet"
J: "Rt external iliac LN"
K: "Right hypogastric/obturator LN"
L: "Left external iliac LN"
M: "Left LN of Cloquet"
N: "Left obturator"
O: "Para aortic LN"
P: "Proximal left ureter"
Q: "Right proximal ureter"

DIAGNOSIS:

RADICAL CYSTECTOMY WITH ILEAL CONDUIT:

RETROPERITONEUM" [PERIAORTA] (A):

FROZEN SECTION DIAGNOSIS:

- METASTATIC CARCINOMA

FINAL DIAGNOSIS:

- METASTATIC UROTHELIAL CARCINOMA

RIGHT PERIRENAL LYMPH NODE (B):

FROZEN SECTION DIAGNOSIS:

- METASTATIC CARCINOMA

FINAL DIAGNOSIS:

- METASTATIC UROTHELIAL CARCINOMA

RIGHT URETER (C):

FROZEN SECTION DIAGNOSIS:

- MILD TO MODERATE ATYPIA OF URETER

- METASTATIC UROTHELIAL CARCINOMA

FINAL DIAGNOSIS:

- MILD ATYPIA OF URETER

- METASTATIC UROTHELIAL CARCINOMA

LEFT URETER (D):

Printed by:

Printed on:

Page 5 of 7
(Continued)

[page 6 of 7]
SURGICAL PATHOLOGY REPORT

* Final Report *

FROZEN SECTION DIAGNOSIS:

- SEVERE DYSPLASIA OF URETER

FINAL DIAGNOSIS:

- SEVERE DYSPLASIA OF URETER
- MICROSCOPIC METASTATIC UROTHELIAL CARCINOMA

BLADDER, PROSTATE AND RECTUM (E):

BLADDER:

- INVASIVE, MODERATELY TO POORLY DIFFERENTIATED PAPILLARY UROTHELIAL CARCINOMA, EXTENDING THROUGH MUSCULARIS PROPRIA INTO PERIVESICAL FAT AND RECTUM
- PAPILLARY UROTHELIAL CARCINOMA, GRADE 3/4
- PERINEURAL AND LYMPHOVASCULAR SPACE INVASION IDENTIFIED
- BILATERAL SEMINAL VESICLES AND VASA DEFERENTIA INVOLVED BY TUMOR

COLON:

- METASTATIC UROTHELIAL CARCINOMA INVOLVING MUSCULAR WALL AND SUBMUCOSA
- DISTAL RESECTION MARGIN INVOLVED BY UROTHELIAL CARCINOMA
- PROXIMAL RESECTION MARGIN, FREE OF TUMOR

PROSTATE:

- BENIGN GLANDULAR AND STROMAL HYPERPLASIA

RIGHT COMMON ILIAC LYMPH NODES (F):

- METASTATIC CARCINOMA IDENTIFIED IN ONE OF THREE LYMPH NODES (1/3)
- PERINODAL LYMPHATIC SPACE INVOLVEMENT

PARACAVAL LYMPH NODES (G):

- NO TUMOR IDENTIFIED IN 11 LYMPH NODES (0/11)

LEFT COMMON ILIAC LYMPH NODES (H):

- NO TUMOR IDENTIFIED IN SEVEN LYMPH NODES (0/7)

RIGHT LYMPH NODE OF CLOQUET (I):

- NO TUMOR IDENTIFIED IN ONE LYMPH NODE (0/1)

RIGHT EXTERNAL ILIAC LYMPH NODES (J):

- METASTATIC CARCINOMA IDENTIFIED IN ONE OF 14 LYMPH NODES (1/14)

RIGHT HYPOGASTRIC/OBTURATOR LYMPH NODES (K):

- NO TUMOR IDENTIFIED IN 23 LYMPH NODES (0/23)

LEFT EXTERNAL ILIAC LYMPH NODES (L):

- NO TUMOR IDENTIFIED IN SEVEN LYMPH NODES (0/7)

Printed by:

Printed on:

Page 6 of 7
(Continued)

[page 7 of 7]
SURGICAL PATHOLOGY REPORT

* Final Report *

- SEGMENT OF VAS DEFERENS

LEFT LYMPH NODE OF CLOQUET (M):

- NO TUMOR IDENTIFIED IN ONE LYMPH NODE (0/1)

LEFT OBTURATOR/HYPOGASTRIC LYMPH NODES (N):

- METASTATIC CARCINOMA IDENTIFIED IN ONE OF 24 LYMPH NODES (1/24)

PARA-AORTIC LYMPH NODES (O):

- METASTATIC CARCINOMA IDENTIFIED IN TWO LYMPH NODES (2/2)

LEFT PROXIMAL URETER (P):

- MICROSCOPIC METASTATIC UROTHELIAL CARCINOMA
- BENIGN UROTHELIAL MUCOSA

RIGHT PROXIMAL URETER (Q):

- MICROSCOPIC METASTATIC UROTHELIAL CARCINOMA
- BENIGN UROTHELIAL MUCOSA

PATHOLOGIC TNM STAGE: pT4a, N2 (5/93), M1

Signature Line

Printed by:
Printed on:

Page 7 of 7
(End of Report)

Source: NCI Genomic Data Commons file be9c7101-ee9a-4376-b8f9-0bb640a108a2 (TCGA-XF-A9SV.5C45E09E-9B8A-4CD4-92CC-873CF78D2524.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).